Somatic mutation profile of tumor specimen TCGA-XA-A8JR-01A (aliquot TCGA-XA-A8JR-01A-11D-A364-08) from TCGA case TCGA-XA-A8JR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.7 years (25,090 days).
Specimen TCGA-XA-A8JR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf5a950c-f258-4da9-9117-7bf4c7b9c296.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XA-A8JR-10A (Blood Derived Normal), aliquot TCGA-XA-A8JR-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8483ee05-179e-477b-9c5b-f793ac736e6b

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC110 | c.115+1G>C p.X39_splice | Splice Site (SNP) | VAF 40/180 reads (22%) | catalogued as COSV100293993; called by muse, mutect2, varscan2
- CDC42EP3 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99767897; called by muse, mutect2, varscan2
- CHRM2 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.105); catalogued as COSV100281427, COSV57769210, COSV57784979; called by muse, mutect2
- FBN3 | c.5956A>G p.T1986A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99561113; called by muse, mutect2
- GZF1 | c.1436T>A p.I479N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.642); catalogued as COSV100582569; called by muse, mutect2, varscan2
- MYCBP2 | c.8645C>G p.S2882C (on ENST00000357337; = p.S2920C on NM_015057.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100630630; called by muse, mutect2, varscan2
- MYSM1 | c.2328A>C p.K776N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101284050; called by muse, mutect2, varscan2
- NME1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99184031; called by muse, mutect2, varscan2
- RBM12 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100467600; called by muse, mutect2
- SEPTIN11 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99346443; called by muse, mutect2, varscan2
- SPANXD | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs781800119, COSV65152302; called by muse, mutect2
- TSGA10 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100747595; called by muse, mutect2, varscan2
- ZNF512 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1479358942; called by muse, mutect2
- HIVEP3 | c.3773del p.L1258Rfs*126 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel, varscan2
- KDM6A | c.1028dup p.C343Wfs*21 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- LYST | c.5900_5908del p.L1967_C1970delinsR | In Frame Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- SELENOI | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- CD63 | c.195C>T p.F65= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV57676777, COSV99141806; called by muse, mutect2, varscan2
- COL12A1 | c.2598C>T p.T866= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as rs1326006851, COSV100486105; called by muse, mutect2, varscan2
- PCDHA7 | c.1989C>T p.A663= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs558442824, COSV100970805; called by muse, mutect2, varscan2
- UTP4 | c.1491T>C p.N497= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100077004; called by muse, mutect2, varscan2
- OBSCN | c.11659+3565G>A | Intron (SNP) | VAF 5/68 reads (7%) | catalogued as COSV52844235, COSV99479861; called by muse, mutect2
- RREB1 | c.3809-5967T>A | Intron (SNP) | VAF 19/104 reads (18%) | catalogued as COSV100619430; called by muse, mutect2, varscan2
